Somatic mutation profile of tumor specimen TCGA-ER-A19M-06A (aliquot TCGA-ER-A19M-06A-61D-A23B-08) from TCGA case TCGA-ER-A19M, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 39.1 years (14,287 days).
Specimen TCGA-ER-A19M-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25a296b9-b371-40cf-a256-7a623f089a4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19M-10A (Blood Derived Normal), aliquot TCGA-ER-A19M-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/176574dc-36a9-48b0-a192-b109dd0b46fb

The open-access MAF lists 590 somatic variants for this specimen: 370 protein-altering or splice-affecting, 206 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 338, Silent 206, Nonsense Mutation 25, Intron 7, RNA 4, Splice Site 3, Frame Shift Del 2, Splice Region 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A2M | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.053); catalogued as COSV59382569; called by muse, mutect2, varscan2
- ABCA3 | c.159C>G p.N53K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV57049259, COSV57053114; called by muse, mutect2, varscan2
- ABCC12 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV60911393; called by muse, mutect2, varscan2
- ABI3BP | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as COSV52527568; called by muse, mutect2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by muse, mutect2, varscan2
- ACSM4 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV68066569; called by muse, mutect2, varscan2
- ACVR1C | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as rs775081249, COSV54643616; called by muse, mutect2, varscan2
- ADAMTS18 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51398418; called by muse, mutect2, varscan2
- ADAMTS18 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs768100645, COSV51398426; called by muse, mutect2, varscan2
- ADGRG7 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56293472; called by muse, mutect2, varscan2
- AEBP2 | c.751A>C p.S251R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV56861406; called by muse, mutect2, varscan2
- AFF4 | c.2114T>G p.L705R | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54791268; called by muse, mutect2, varscan2
- AGFG2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as rs1018491385, COSV53543888; called by muse, mutect2, varscan2
- AGTR1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 64/130 reads (49%) | catalogued as rs1417391173, COSV62557140; called by muse, mutect2, varscan2
- AHDC1 | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as COSV55936511; called by muse, mutect2, varscan2
- AHNAK | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747760505, COSV57203064; called by muse, mutect2, varscan2
- AKAP13 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV63447826; called by muse, mutect2, varscan2
- AKAP4 | c.1245G>A p.W415* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | catalogued as COSV62073590; called by muse, mutect2, varscan2
- AKR1C3 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV65910048; called by muse, mutect2, varscan2
- AKR1C4 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs781788408, COSV54122205; called by muse, mutect2, varscan2
- ALOXE3 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.102); catalogued as COSV59073802; called by muse, mutect2, varscan2
- ALPL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs138587317, CM1512156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMPD1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62414954, COSV62417076, COSV62418845; called by muse, mutect2, varscan2
- ANGEL1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.115); catalogued as rs1372811579, COSV51871807; called by muse, mutect2, varscan2
- ANGPTL1 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52365298; called by muse, mutect2, varscan2
- ANK2 | c.5615C>T p.S1872L | Missense Mutation (SNP) | VAF 83/159 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as rs775953030, COSV52144649, COSV52150813; called by muse, mutect2, varscan2
- AOC1 | c.1363A>G p.T455A | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as COSV62866750; called by muse, mutect2, varscan2
- AP1B1 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58014325; called by muse, mutect2, varscan2
- APC | c.6700C>T p.P2234S | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749507584, COSV57323225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF3 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.328); catalogued as COSV52449768; called by muse, mutect2, varscan2
- ARPP21 | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51791713; called by muse, mutect2, varscan2
- ATAD2B | c.3716C>T p.S1239L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1330937007, COSV53194876; called by muse, mutect2, varscan2
- ATP13A5 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60865432; called by muse, mutect2, varscan2
- ATP1B1 | c.227-1G>A p.X76_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100891647, COSV63178803; called by muse, mutect2
- ATP2B4 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs267598314, COSV58174204; called by muse, mutect2, varscan2
- ATP6V1H | c.579+2T>A p.X193_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV62216729, COSV62219333; called by muse, varscan2
- BAG3 | c.636C>G p.H212Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150379892, COSV64841587; called by muse, mutect2, varscan2
- BEND2 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.031); catalogued as COSV66219898; called by muse, mutect2, varscan2
- BMP4 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs746478907, COSV55415074; called by muse, mutect2, varscan2
- BPIFB2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs748992554, COSV50063090; called by muse, mutect2, varscan2
- C2CD3 | c.4951G>A p.G1651R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58089285; called by muse, mutect2, varscan2
- CACNA1I | c.4855G>A p.V1619M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100359579; called by muse, mutect2, varscan2
- CAMK2B | c.219C>T p.I73= | Splice Region (SNP) | VAF 36/86 reads (42%) | catalogued as rs371901503; called by muse, mutect2, varscan2
- CAMSAP2 | c.2960G>A p.R987K (on ENST00000236925 / NM_001297707.2; = p.R976K on NM_203459.3) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV52666624; called by muse, mutect2, varscan2
- CCDC173 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.09); catalogued as COSV69572467, COSV69572787; called by muse, mutect2, varscan2
- CCDC191 | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV55669965; called by muse, mutect2, varscan2
- CD300E | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as COSV60789750; called by mutect2, varscan2
- CDH10 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV100051463, COSV52569250; called by muse, mutect2, varscan2
- CDH19 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV50954263; called by mutect2, varscan2
- CEACAM20 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.049); catalogued as COSV57600748; called by mutect2, varscan2
- CEP250 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.55); catalogued as rs780050066, COSV61168041; called by muse, mutect2, varscan2
- CFHR3 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV66401439; called by muse, mutect2, varscan2
- CFHR5 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs779001368, COSV56817744; called by muse, mutect2, varscan2
- CHGB | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66759545; called by muse, mutect2, varscan2
- CNOT1 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV57763804; called by muse, mutect2, varscan2
- CNOT1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs369419200; called by muse, mutect2, varscan2
- CNOT1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57763841; called by muse, mutect2, varscan2
- CNOT10 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs201770145, COSV59390000; called by muse, mutect2
- CNTNAP2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs867001883, COSV100665155, COSV62143236; called by muse, mutect2, varscan2
- COG8 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV54741656; called by muse, mutect2, varscan2
- COL14A1 | c.5066C>T p.P1689L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52846813; called by muse, mutect2
- COL20A1 | c.3755G>A p.R1252H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs773306691, COSV58911351; called by muse, mutect2, varscan2
- COL4A4 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61629391; called by muse, mutect2
- COL6A3 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV55078961; called by muse, mutect2, varscan2
- COX10 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55401937; called by muse, mutect2, varscan2
- CPA5 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1352380933, COSV62568673; called by muse, mutect2
- CRNN | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 50/236 reads (21%) | catalogued as COSV55120622; called by muse, mutect2, varscan2
- CSMD1 | c.3532G>A p.E1178K (on ENST00000520002; = p.E1177K on NM_033225.6) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV59279307; called by muse, mutect2
- CSMD2 | c.1796G>A p.G599D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV53876702; called by muse, mutect2, varscan2
- CSMD2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV53876721, COSV99597269; called by muse, mutect2, varscan2
- CSTF3 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV60609324; called by muse, mutect2, varscan2
- CTBS | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV55361077; called by muse, mutect2, varscan2
- CTNNA2 | c.1175T>A p.F392Y | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV58133189, COSV58138675; called by muse, mutect2, varscan2
- CXCR2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.137); catalogued as rs868597455, COSV59279680; called by muse, mutect2, varscan2
- CYP26A1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56416825; called by muse, mutect2, varscan2
- CYP26B1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV50010646; called by muse, mutect2, varscan2
- CYP4B1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766821883, COSV54721061; called by muse, mutect2, varscan2
- DAB1 | c.850G>A p.D284N (on ENST00000371231; = p.D251N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as COSV64689968; called by muse, mutect2, varscan2
- DENND1A | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV65322134, COSV65322181; called by muse, mutect2, varscan2
- DENND5A | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV60231206; called by muse, mutect2, varscan2
- DES | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs1060503169, COSV64659761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX8 | c.3230A>G p.D1077G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52250816; called by muse, varscan2
- DLGAP4 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as rs747346486, COSV59414175; called by muse, mutect2, varscan2
- DMBT1 | c.3353C>T p.S1118F (on ENST00000338354 / NM_001377530.1; = p.S619F on NM_004406.3) | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100352462; called by mutect2, varscan2
- DMBT1 | c.6170G>A p.G2057E (on ENST00000338354 / NM_001377530.1; = p.G1300E on NM_004406.3) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100352918, COSV57533673, COSV57559889; called by muse, mutect2, varscan2
- DMC1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs1300163639, COSV53258029; called by muse, mutect2, varscan2
- DNAH17 | c.11738G>A p.G3913E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1368100824, COSV67749393; called by muse, mutect2, varscan2
- DNAH3 | c.10144A>C p.M3382L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54502440; called by muse, mutect2, varscan2
- DNAH5 | c.9043G>A p.D3015N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54202716, COSV54233131; called by muse, mutect2, varscan2
- DNAH5 | c.5776G>A p.E1926K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs771222700, COSV54202729, COSV99454399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as COSV56751062; called by muse, mutect2
- DNAH9 | c.2308C>T p.L770F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV52332784; called by muse, mutect2, varscan2
- DPYSL2 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV60781746; called by muse, mutect2, varscan2
- DSG1 | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV104377459, COSV57133056; called by muse, mutect2, varscan2
- DTNA | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV51989791; called by muse, mutect2, varscan2
- DYNAP | c.336G>A p.W112* (on ENST00000321600; = p.W86* on NM_173629.3) | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV58665945; called by muse, mutect2, varscan2
- E2F8 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs867022691, COSV51461648; called by muse, mutect2, varscan2
- E4F1 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57037526; called by muse, mutect2, varscan2
- ECI2 | c.835C>T p.P279S (on ENST00000380118 / NM_206836.3; = p.P249S on NM_006117.2) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60984859; called by muse, mutect2, varscan2
- EFCAB7 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64313883, COSV64315530; called by muse, mutect2
- EIF4G3 | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV51673534; called by muse, mutect2, varscan2
- ELF1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV53496843; called by muse, mutect2, varscan2
- EPHB2 | c.2346T>G p.S782R (on ENST00000400191 / NM_001309193.2; = p.S783R on NM_004442.7) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV65859714; called by muse, mutect2, varscan2
- EVPL | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV56907154; called by muse, mutect2, varscan2
- FAAH2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV66504818; called by muse, mutect2, varscan2
- FAH | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55720023; called by muse, mutect2, varscan2
- FAM47C | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV63723515; called by muse, mutect2, varscan2
- FAM83B | c.177A>T p.E59D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV60919128; called by muse, mutect2, varscan2
- FBN1 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs781147556, COSV57308778; called by muse, mutect2, varscan2
- FLG | c.4454G>A p.G1485D | Missense Mutation (SNP) | VAF 115/451 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV64236092; called by muse, mutect2, varscan2
- FLG2 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.234); catalogued as rs778614508, COSV66166513; called by muse, mutect2, varscan2
- FLNC | c.5369C>T p.P1790L | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57949866; called by muse, mutect2, varscan2
- FMO2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946544; called by muse, mutect2, varscan2
- FOLH1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267602925, COSV57045271; called by muse, mutect2, varscan2
- FOSL2 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99268252; called by muse, mutect2, varscan2
- FOSL2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.795); catalogued as COSV53105614; called by muse, mutect2
- FPR2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60671809; called by muse, mutect2, varscan2
- FRMD1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as rs774519671, COSV51959824; called by muse, mutect2
- GABPB2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64460460; called by muse, mutect2, varscan2
- GABRG1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs568096519, COSV54949731; called by muse, mutect2, varscan2
- GAK | c.2966C>T p.S989F | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs893361522, COSV58502685; called by muse, mutect2, varscan2
- GALR1 | c.824T>C p.F275S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs951157029, COSV55315739; called by muse, varscan2
- GAMT | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV52038252; called by muse, mutect2, varscan2
- GCG | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs5650; called by muse, mutect2, varscan2
- GDF5 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV65499198; called by muse, mutect2, varscan2
- GFRAL | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 33/195 reads (17%) | catalogued as COSV61228659; called by muse, mutect2, varscan2
- GHR | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs199937609, COSV50105878; called by muse, mutect2, varscan2
- GJA5 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV54782840; called by muse, mutect2, varscan2
- GKN2 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as rs368576390; called by muse, mutect2, varscan2
- GORASP2 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs773846268, COSV52200776; called by muse, mutect2, varscan2
- GPR158 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771481056, COSV66264917; called by muse, mutect2, varscan2
- GRIK1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV58710085; called by muse, mutect2, varscan2
- GRIN2A | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58019197; called by muse, mutect2, varscan2
- GRIN2B | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101662960; called by muse, mutect2, varscan2
- GRIN3A | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62450389; called by muse, mutect2, varscan2
- GRIP2 | c.2452C>T p.H818Y (on ENST00000619221; = p.H721Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1253853439, COSV56119532; called by muse, mutect2, varscan2
- GRN | c.350-1G>A p.X117_splice | Splice Site (SNP) | VAF 23/96 reads (24%) | catalogued as COSV50006135, COSV99275104; called by muse, mutect2, varscan2
- GTF3C3 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV55830816; called by muse, mutect2, varscan2
- H1-5 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV100137764; called by muse, mutect2, varscan2
- HBD | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs35329985, CM820009, COSV53081910, COSV53083920; ClinVar: other; called by muse, mutect2, varscan2
- HHATL | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV55132602; called by muse, mutect2, varscan2
- HINFP | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV63431567; called by muse, mutect2, varscan2
- HLCS | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60791187; called by muse, mutect2, varscan2
- HNRNPCL1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58609873; called by muse, mutect2, varscan2
- HYAL2 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63305831; called by muse, mutect2, varscan2
- IGKV1-27 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as rs1240926481; called by muse, mutect2, varscan2
- IGSF9 | c.1276G>A p.E426K (on ENST00000368094 / NM_001135050.2; = p.E410K on NM_020789.4) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as COSV63638710; called by muse, mutect2, varscan2
- IL1R2 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV60205522; called by muse, mutect2, varscan2
- IL36B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52084330; called by muse, mutect2, varscan2
- ILDR1 | c.1135G>A p.E379K (on ENST00000344209 / NM_001199799.2; = p.E335K on NM_175924.4) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as CM110958, COSV56547398; called by muse, mutect2, varscan2
- IQSEC3 | c.2564C>T p.S855F (on ENST00000538872 / NM_001170738.2; = p.S552F on NM_015232.1) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV58280274; called by muse, mutect2, varscan2
- ITGA4 | c.2876T>C p.V959A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV59202751; called by muse, mutect2
- ITGA7 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs750316122, COSV57691445; called by muse, mutect2, varscan2
- ITGAD | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.172); catalogued as rs767114358, COSV66756678; called by muse, mutect2, varscan2
- ITGBL1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs267603743, COSV66004925; called by muse, mutect2, varscan2
- ITIH1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 35/58 reads (60%) | catalogued as COSV56251890; called by muse, mutect2, varscan2
- ITK | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs138078237, COSV68435214, COSV68435506; called by muse, mutect2, varscan2
- JAKMIP1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV51521827; called by muse, mutect2, varscan2
- KAT6B | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV99767571; called by muse, mutect2, varscan2
- KCNB2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.226); catalogued as rs778910036, COSV73048799; called by muse, mutect2, varscan2
- KDM4C | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67183475; called by muse, mutect2, varscan2
- KIAA1217 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as COSV56812104; called by muse, mutect2, varscan2
- KMT2D | c.12592C>G p.R4198G | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as CM122102, COSV56409006, COSV56429446; called by muse, mutect2, varscan2
- KPNA3 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55503078; called by muse, mutect2, varscan2
- KRT12 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV52429644; called by muse, mutect2, varscan2
- KRT6A | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV58103535; called by muse, mutect2
- L3MBTL4 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs370465816; called by muse, mutect2, varscan2
- LCE3B | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV59500427; called by muse, mutect2, varscan2
- LHCGR | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866954326, COSV54292036; called by muse, mutect2
- LIFR | c.1891C>T p.L631F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV54684166; called by muse, mutect2, varscan2
- LMAN1L | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV59000501; called by muse, mutect2, varscan2
- LPA | c.4769C>T p.P1590L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV60296164; called by muse, mutect2, varscan2
- LRFN2 | c.1257A>T p.K419N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV57823496; called by muse, mutect2, varscan2
- LRP1B | c.5327A>T p.E1776V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.368); catalogued as COSV67184434; called by muse, mutect2, varscan2
- LRP2 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55539966; called by muse, mutect2, varscan2
- LRP2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs747942310, COSV55539979; called by muse, mutect2, varscan2
- LRPPRC | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV53233759; called by muse, mutect2, varscan2
- LRRC30 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV67301271; called by muse, mutect2, varscan2
- LTBP2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV56204540; called by muse, mutect2
- MAEL | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63303802; called by muse, mutect2, varscan2
- MAP3K5 | c.4066G>A p.G1356R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62886855; called by muse, mutect2, varscan2
- MAPT | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.553); catalogued as rs751685945, COSV52236820; called by muse, mutect2, varscan2
- MASTL | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs267602456, COSV100668875, COSV60909334; called by muse, mutect2, varscan2
- MATN4 | c.1543G>A p.E515K (on ENST00000372754; = p.E474K on NM_003833.4) | Missense Mutation (SNP) | VAF 31/128 reads (24%) | PolyPhen benign (0.426); catalogued as COSV61350273; called by muse, mutect2, varscan2
- MCF2L2 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419114797, COSV61048711; called by muse, mutect2, varscan2
- MDN1 | c.7789C>T p.P2597S | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs770523055, COSV65516851; called by muse, mutect2, varscan2
- MDN1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65516854; called by muse, mutect2, varscan2
- MECOM | c.1877C>T p.S626F (on ENST00000468789 / NM_001105078.4; = p.S814F on NM_004991.4) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52959070, COSV52960579; called by muse, mutect2
- MED1 | c.2123T>G p.F708C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56122239; called by muse, mutect2, varscan2
- MEI1 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV55900323; called by muse, mutect2, varscan2
- MROH7 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs763807533, COSV64886431; called by muse, mutect2, varscan2
- MST1R | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs770576642, COSV56564212; called by muse, mutect2, varscan2
- MTUS2 | c.2351G>A p.R784K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV70912899; called by muse, mutect2, varscan2
- MUC16 | c.24256C>T p.P8086S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as rs1207498258, COSV67443084; called by muse, mutect2, varscan2
- MUC16 | c.9794G>A p.G3265E | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs866469293, COSV67443092; called by muse, mutect2, varscan2
- MUC16 | c.5365G>A p.E1789K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1353529830, COSV67443099; called by muse, mutect2, varscan2
- MVP | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs769739441, COSV62421306; called by muse, mutect2, varscan2
- MYH3 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs756833381, COSV56860649, COSV56867377; called by muse, mutect2, varscan2
- MYH4 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1368046636, COSV55111807; called by muse, mutect2, varscan2
- MYLPF | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV100363009; called by muse, mutect2, varscan2
- MYOCD | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV58496972; called by muse, varscan2
- MYRIP | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV56861408; called by muse, mutect2, varscan2
- NEU2 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774136106, COSV52092667; called by muse, mutect2, varscan2
- NEU2 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99290490; called by muse, mutect2, varscan2
- NKX2-2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as COSV65819133; called by muse, mutect2, varscan2
- NLRC3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57086822; called by muse, mutect2, varscan2
- NLRP1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.114); catalogued as rs1254455800, COSV52558007; called by muse, mutect2, varscan2
- NOB1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1382174482, COSV52060618; called by muse, mutect2, varscan2
- NOMO1 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55056903; called by muse, mutect2, varscan2
- NR4A3 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1159997688, COSV58243100; called by muse, mutect2, varscan2
- NTRK1 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761967383, COSV62323124; called by muse, mutect2, varscan2
- NUP98 | c.4051C>T p.Q1351* (on ENST00000359171 / NM_001365126.1; = p.Q1334* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/156 reads (22%) | catalogued as COSV61428250; called by muse, mutect2, varscan2
- NXF1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV53672065, COSV53672965; called by muse, mutect2, varscan2
- NXPE3 | c.1176C>A p.F392L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV56289778, COSV99839833; called by muse, mutect2, varscan2
- NXPE3 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV56289591; called by muse, mutect2, varscan2
- OBSCN | c.8551T>C p.S2851P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759737291, COSV52737907; called by muse, mutect2
- ODF4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV60271587; called by muse, mutect2, varscan2
- OLR1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV58870846; called by muse, mutect2, varscan2
- OR13C3 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV66165583; called by muse, mutect2, varscan2
- OR4N5 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV61320004; called by muse, mutect2, varscan2
- OR51E2 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs867888582, COSV67806638; called by muse, mutect2, varscan2
- OR52E6 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs1445038074, COSV61431250; called by muse, mutect2, varscan2
- OR52L1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762784705, COSV59985620; called by muse, mutect2, varscan2
- OR56A3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs777153187, COSV61568506, COSV61569191; called by muse, varscan2
- OR5AC2 | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV104423230, COSV62279064; called by muse, mutect2, varscan2
- OR5D13 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs777852254, COSV100686654, COSV62332645; called by muse, mutect2, varscan2
- OR6B3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV60112553; called by muse, mutect2, varscan2
- OR6C2 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV59515511; called by muse, mutect2, varscan2
- OR6K2 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV62743053, COSV62743882; called by muse, mutect2, varscan2
- OSBPL7 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1341492129, COSV50106514; called by muse, mutect2, varscan2
- PAQR4 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV51890819; called by muse, mutect2, varscan2
- PCDHA11 | c.2125C>T p.L709F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100250698, COSV56475927; called by muse, mutect2, varscan2
- PCDHAC1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs781951426, COSV53836246; called by muse, mutect2, varscan2
- PCDHB12 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); catalogued as rs1554286787, COSV53392865; called by muse, mutect2, varscan2
- PCNT | c.6760T>G p.C2254G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV64024803; called by muse, mutect2, varscan2
- PDGFRB | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as COSV53846471; called by muse, mutect2, varscan2
- PDGFRB | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs374003999, COSV53842418; called by muse, mutect2, varscan2
- PDGFRB | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777708927, COSV55800476; called by muse, mutect2, varscan2
- PDZD4 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.647); catalogued as rs1557076222, COSV51245275; called by muse, mutect2, varscan2
- PEX11A | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs756263730, COSV100261437, COSV55582751; called by muse, mutect2, varscan2
- PFKFB4 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 35/60 reads (58%) | PolyPhen benign (0); catalogued as COSV51679437; called by muse, mutect2, varscan2
- PHC3 | c.385C>T p.L129F (on ENST00000494943 / NM_001308116.2; = p.L141F on NM_024947.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV63051419; called by muse, mutect2, varscan2
- PHIP | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV51501283; called by muse, mutect2
- PI3 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.063); catalogued as rs879000985, COSV54782833; called by muse, mutect2, varscan2
- PIAS2 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV61342040; called by muse, mutect2, varscan2
- PKD1L1 | c.8392G>A p.E2798K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs755846293, COSV51841256; called by muse, mutect2, varscan2
- PKDREJ | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV53546279; called by muse, mutect2, varscan2
- PKHD1L1 | c.5009C>T p.S1670L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65736553; called by muse, mutect2, varscan2
- PKN2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1299447136, COSV60129713; called by muse, mutect2, varscan2
- PLCG1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750533169, COSV54814970; called by muse, mutect2, varscan2
- PLCL1 | c.2555G>A p.G852E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV70820777, COSV70871839; called by muse, mutect2, varscan2
- PLD1 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60565174; called by muse, mutect2, varscan2
- PLEKHA7 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370703601; called by muse, mutect2, varscan2
- PLXNB1 | c.5401C>T p.R1801C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs759846178, COSV56486536; called by muse, mutect2, varscan2
- PNMT | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54092313; called by muse, mutect2, varscan2
- POM121L12 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs764722281, COSV68692179; called by muse, varscan2
- PPFIA2 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61019801; called by muse, mutect2, varscan2
- PPHLN1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV56728203; called by muse, mutect2, varscan2
- PRAMEF10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs201689660; called by muse, mutect2, varscan2
- PRICKLE1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759969939, COSV61547493; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.866T>G p.V289G (on ENST00000352766; = p.V166G on NM_181334.5) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs201465628, COSV61231536; called by muse, mutect2, varscan2
- PSG3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV59502283; called by muse, mutect2, varscan2
- PTCHD3 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs756627726, COSV71256266; called by muse, mutect2, varscan2
- PTK2B | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs1046870960, COSV100594335, COSV57749572; called by muse, mutect2, varscan2
- PTK7 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57846156; called by muse, mutect2, varscan2
- PTPRB | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54231599; called by muse, mutect2, varscan2
- PTPRN2 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67021154; called by muse, mutect2, varscan2
- PTPRR | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs960921519, COSV51724373; called by muse, mutect2, varscan2
- PUS7 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62675755, COSV62678150; called by muse, mutect2, varscan2
- PXK | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100244379, COSV57086339, COSV57087332; called by muse, mutect2, varscan2
- RALGPS2 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757039833, COSV62678168; called by muse, mutect2, varscan2
- RBMXL2 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs1565036366, COSV60978463; called by muse, mutect2, varscan2
- RCAN3 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65558081; called by muse, mutect2
- RCC1 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV65778881; called by muse, mutect2, varscan2
- RLN1 | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 559/587 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV56346074, COSV56346096; called by muse, mutect2, varscan2
- RNASEH1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV59437978; called by muse, mutect2
- ROS1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as rs759714879, COSV63851066; called by muse, mutect2, varscan2
- RPL10L | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1264270481, COSV53558575; called by muse, mutect2, varscan2
- RUNDC1 | c.803A>C p.E268A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.76); catalogued as COSV64511439; called by muse, mutect2
- RUNDC3B | c.884A>T p.N295I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100406871; called by muse, mutect2, varscan2
- SCN5A | c.2339G>A p.G780D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100347073; called by muse, mutect2, varscan2
- SCN5A | c.2338G>A p.G780S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV100347074; called by muse, mutect2, varscan2
- SDC3 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100232168; called by muse, mutect2, varscan2
- SERPINA10 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1227298146, COSV56227398; called by muse, mutect2, varscan2
- SERPINB11 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777776429, COSV66956396; called by muse, mutect2, varscan2
- SERPINB4 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV61984062; called by muse, mutect2, varscan2
- SH3BP4 | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs753252621, COSV60642152; called by muse, mutect2, varscan2
- SHBG | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52646955; called by muse, mutect2, varscan2
- SIGLEC5 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 80/160 reads (50%) | catalogued as rs1389630770, COSV55777267; called by muse, mutect2, varscan2
- SIM1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV99492113; called by muse, mutect2, varscan2
- SLC10A2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs766114543, COSV55356812; called by muse, mutect2, varscan2
- SLC1A2 | c.312G>C p.G104= | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as COSV53518554; called by muse, mutect2
- SLC22A15 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65679520; called by muse, mutect2, varscan2
- SLC26A8 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV62884398; called by muse, mutect2, varscan2
- SLC39A2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV53868815; called by muse, mutect2, varscan2
- SLC4A3 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs1226361754, COSV56091264; called by muse, mutect2, varscan2
- SLC5A8 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV73310344; called by muse, mutect2
- SLC8A3 | c.2135G>A p.G712E (on ENST00000381269 / NM_183002.3; = p.G710E on NM_033262.4) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53687518, COSV99385229; called by muse, mutect2, varscan2
- SLC8A3 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV63518808; called by muse, mutect2, varscan2
- SLITRK1 | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV65674079; called by muse, mutect2, varscan2
- SMARCA4 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060502079, COSV60791743; ClinVar: uncertain significance; called by muse, mutect2
- SMG1 | c.4972C>T p.P1658S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV67169349; called by muse, mutect2, varscan2
- SMYD5 | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50264359; called by muse, mutect2, varscan2
- SNTG2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV57967264; called by muse, mutect2, varscan2
- SOX17 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV52024132, COSV52025877; called by muse, mutect2, varscan2
- SPANXN5 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as COSV64968622; called by muse, mutect2, varscan2
- SPDYE1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV51669334; called by muse, mutect2, varscan2
- SPHKAP | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60868010; called by muse, mutect2, varscan2
- SPN | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs371355682; called by muse, mutect2, varscan2
- STAB2 | c.4691G>A p.G1564D | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66333798; called by muse, mutect2, varscan2
- SYNCRIP | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 82/210 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV62286447; called by muse, mutect2, varscan2
- TACR2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as rs781424764, COSV64821790; called by muse, varscan2
- TCP11L2 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV54428865; called by muse, varscan2
- TENM1 | c.8161G>A p.E2721K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs765774675, COSV64424593; called by muse, mutect2, varscan2
- TET1 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV65381811; called by muse, mutect2, varscan2
- TEX15 | c.1531G>A p.E511K (on ENST00000256246; = p.E894K on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267601898, COSV56341254; called by muse, mutect2, varscan2
- TFEC | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV55397348; called by muse, mutect2, varscan2
- TFF1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52298015; called by muse, mutect2, varscan2
- TGM1 | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52861580; called by muse, mutect2, varscan2
- TGM1 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV52861589; called by muse, mutect2, varscan2
- THSD7B | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55651987; called by muse, mutect2, varscan2
- THSD7B | c.3340G>A p.E1114K (on ENST00000272643; = p.E1112K on NM_001316349.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV55652012; called by muse, mutect2, varscan2
- TIAM2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as COSV59689038; called by muse, mutect2, varscan2
- TMC3 | c.1716G>A p.W572* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs1459251681, COSV63922094; called by muse, mutect2, varscan2
- TMEM63C | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | catalogued as COSV53600998; called by muse, mutect2, varscan2
- TOMM70 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424201; called by muse, mutect2, varscan2
- TOMM70 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424203; called by muse, mutect2, varscan2
- TPTE2 | c.1015G>A p.E339K (on ENST00000400230 / NM_199254.2; = p.E262K on NM_130785.3) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); catalogued as rs140738972, COSV55015799; called by muse, mutect2, varscan2
- TRAF5 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs749244546, COSV54820946; called by muse, mutect2, varscan2
- TRIM49 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs1272314655, COSV61670149, COSV61671980; called by muse, mutect2, varscan2
- TRIM69 | c.1033G>A p.V345I (on ENST00000329464 / NM_182985.5; = p.V186I on NM_080745.5) | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as rs778647787, COSV57802812; called by muse, mutect2, varscan2
- TRPC4 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58989751; called by muse, mutect2, varscan2
- TRPV5 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV54682902; called by muse, varscan2
- TRPV6 | c.1346G>A p.R449K | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV63890325; called by muse, mutect2, varscan2
- TSPEAR | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV100553299, COSV59951141; called by muse, mutect2, varscan2
- TTC21B | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV54627555; called by muse, mutect2, varscan2
- TTC3 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV61285526; called by muse, mutect2, varscan2
- TTN | c.38243C>T p.S12748F (on ENST00000591111; = p.S5324F on NM_003319.4) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | PolyPhen possibly damaging (0.864); catalogued as COSV59874978; called by muse, mutect2, varscan2
- TTN | c.18519G>A p.M6173I (on ENST00000591111; = p.M5246I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | PolyPhen benign (0.019); catalogued as rs746981434, COSV59875019; called by muse, mutect2, varscan2
- TTN | c.16747G>A p.D5583N (on ENST00000591111; = p.D4656N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | PolyPhen probably damaging (0.964); catalogued as COSV59875030; called by muse, mutect2, varscan2
- TULP4 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV65571827; called by muse, mutect2, varscan2
- UBR4 | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs376916180; called by muse, mutect2, varscan2
- UCK1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV64734843; called by muse, mutect2, varscan2
- UGT1A1 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV59381249; called by muse, mutect2, varscan2
- UGT1A7 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60830741; called by muse, mutect2, varscan2
- UGT2B15 | c.1458G>A p.W486* | Nonsense Mutation (SNP) | VAF 73/157 reads (46%) | catalogued as COSV57732847, COSV57734888; called by muse, mutect2, varscan2
- UGT3A2 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV56928272, COSV56930932; called by muse, mutect2, varscan2
- UMODL1 | c.3479C>T p.T1160I (on ENST00000408910 / NM_001004416.2; = p.T1288I on NM_173568.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68569230; called by muse, mutect2, varscan2
- VASN | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV52027763; called by muse, mutect2, varscan2
- VPS51 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as COSV54205962; called by muse, mutect2, varscan2
- WAS | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782584950, COSV64996580; called by muse, mutect2, varscan2
- WDPCP | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV55412551; called by muse, mutect2, varscan2
- WDR59 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50933106; called by muse, mutect2, varscan2
- WT1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs267602851, COSV100188811, COSV60065760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XPR1 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.726); catalogued as COSV62554348; called by muse, varscan2
- ZBBX | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV56782212; called by muse, mutect2
- ZFHX4 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.157); catalogued as COSV50481893; called by muse, mutect2, varscan2
- ZFHX4 | c.5717G>A p.G1906E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50481966; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2044C>G p.Q682E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV60155504; called by muse, mutect2, varscan2
- ZNF479 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs782397414, COSV58635674, COSV58644232; called by muse, varscan2
- ZNF555 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1298310593, COSV62072716; called by muse, mutect2, varscan2
- ZNF750 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1234682267, COSV53958328, COSV99489813; called by muse, mutect2, varscan2
- ANGPT1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ARAP2 | c.1943_1952del p.F648Sfs*28 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- IGHV3-53 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KMT2A | c.9846_9867del p.P3283Nfs*30 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- SRSF10 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV2 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF26 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- AC013489.1 | c.360C>T p.L120= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV51550038; called by muse, mutect2, varscan2
- ACE | c.3180C>T p.I1060= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs754344947, COSV52003209; called by muse, mutect2, varscan2
- ACSM2A | c.291C>T p.L97= (on ENST00000219054; = p.L18= on NM_001308169.2) | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV54582022; called by muse, mutect2, varscan2
- ACSM2B | c.291C>T p.L97= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV61656614; called by muse, mutect2, varscan2
- ACTL8 | c.432C>T p.T144= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs370630395; called by muse, mutect2, varscan2
- ADCY3 | c.1602C>T p.P534= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs560448517, COSV53164127; called by muse, mutect2, varscan2
- AKR1D1 | c.324C>T p.V108= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs762814083, COSV54336041; called by muse, mutect2, varscan2
- ALG3 | c.1113C>T p.L371= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV56610014; called by muse, mutect2, varscan2
- ALG6 | c.244C>T p.L82= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV54763105; called by muse, mutect2, varscan2
- ALK | c.2145G>A p.G715= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV66556498; called by muse, mutect2, varscan2
- AMOT | c.2577C>T p.S859= (on ENST00000371959 / NM_001113490.1; = p.S450= on NM_133265.3) | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1447806434, COSV59060279; called by muse, mutect2, varscan2
- ANO1 | c.1797G>A p.E599= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV60280951; called by muse, mutect2, varscan2
- ANO2 | c.363C>T p.I121= (on ENST00000356134 / NM_001278597.3; = p.I125= on NM_001278596.3) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs199524450, COSV59007034; called by muse, mutect2, varscan2
- ANO9 | c.240C>T p.I80= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100241119, COSV60448039; called by muse, mutect2, varscan2
- AOC3 | c.936C>T p.P312= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53824048; called by muse, mutect2, varscan2
- APBB2 | c.1230C>T p.I410= (on ENST00000295974 / NM_001166050.2; = p.I411= on NM_004307.2) | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV55946755; called by muse, mutect2, varscan2
- APOB | c.10434C>T p.D3478= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV51922299; called by muse, mutect2, varscan2
- ARHGEF9 | c.1023C>T p.F341= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV53634044; called by muse, mutect2, varscan2
- ARMC4 | c.1134T>C p.N378= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV53462390, COSV99518482; called by muse, mutect2, varscan2
- ASH1L | c.6601C>T p.L2201= (on ENST00000368346 / NM_001366177.2; = p.L2196= on NM_018489.3) | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV64205243; called by muse, mutect2
- ASIC1 | c.813C>T p.T271= | Silent (SNP) | VAF 45/217 reads (21%) | catalogued as COSV57315996; called by muse, mutect2, varscan2
- ATP1B4 | c.27G>A p.R9= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as COSV54311102, COSV54315336; called by muse, mutect2, varscan2
- ATP8A2 | c.1449G>T p.L483= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV54935612; called by muse, mutect2, varscan2
- ATP8B2 | c.970C>T p.L324= (on ENST00000672630; = p.L291= on NM_001005855.2) | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV59244564; called by muse, mutect2, varscan2
- BIN2 | c.39C>T p.F13= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV53328845; called by muse, mutect2, varscan2
- C1QL2 | c.531C>T p.F177= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55605904; called by muse, mutect2, varscan2
- C8A | c.861C>T p.F287= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs1317217731, COSV63483018; called by muse, mutect2, varscan2
- CATSPERB | c.1689G>A p.T563= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs750466448, COSV56421945; called by muse, mutect2, varscan2
- CBLN2 | c.582G>A p.R194= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV54050171; called by muse, mutect2, varscan2
- CCDC137 | c.636C>T p.P212= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100235605, COSV61302899; called by muse, mutect2, varscan2
- CCDC39 | c.1309T>C p.L437= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV56478194; called by muse, mutect2, varscan2
- CCDC88B | c.2064G>A p.G688= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV57264807; called by muse, mutect2, varscan2
- CD163L1 | c.2430G>A p.V810= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV58010578; called by muse, mutect2, varscan2
- CD163L1 | c.1524G>A p.R508= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV58010588; called by muse, mutect2, varscan2
- CD300LF | c.66C>T p.I22= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV56895541; called by muse, mutect2, varscan2
- CD8B | c.720C>T p.I240= (on ENST00000331469 / NM_172213.4; = p.I210= on NM_172102.4) | Silent (SNP) | VAF 70/324 reads (22%) | catalogued as COSV58924897; called by muse, mutect2, varscan2
- CDH20 | c.2115C>T p.I705= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV53004159; called by muse, mutect2, varscan2
- CDH22 | c.795C>T p.I265= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs1298643641, COSV64836427; called by muse, varscan2
- CES1 | c.1251C>T p.F417= (on ENST00000361503 / NM_001025194.2; = p.F416= on NM_001266.5) | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs747893163, COSV62085317, COSV62086208; called by muse, mutect2, varscan2
- CETP | c.801C>T p.F267= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV52361303; called by muse, mutect2, varscan2
- CHRDL2 | c.633G>A p.P211= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs146704420; called by muse, mutect2, varscan2
- CKAP4 | c.1308C>T p.S436= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs751356737, COSV65172114; called by muse, mutect2, varscan2
- CNGA1 | c.1164C>T p.I388= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs550831196, COSV62052849; called by muse, mutect2, varscan2
- COL6A1 | c.867C>G p.P289= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs751609584, COSV100720429, COSV62611365, COSV62612528; called by muse, mutect2, varscan2
- COL6A3 | c.3381G>A p.R1127= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV55078935; called by muse, mutect2, varscan2
- CPAMD8 | c.1752G>A p.E584= (on ENST00000651564; = p.E537= on NM_015692.5) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52230852; called by muse, mutect2, varscan2
- CRACR2A | c.1113C>T p.F371= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52909973; called by muse, mutect2, varscan2
- DAG1 | c.1092G>A p.G364= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as COSV58182410; called by muse, mutect2, varscan2
- DAGLA | c.2304G>A p.A768= | Silent (SNP) | VAF 92/169 reads (54%) | catalogued as rs768155767, COSV57193797; called by muse, mutect2, varscan2
- DLGAP2 | c.3093C>T p.S1031= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV70093731; called by muse, mutect2, varscan2
- DNHD1 | c.657C>T p.P219= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV54430060; called by muse, mutect2, varscan2
- DNM3 | c.670C>T p.L224= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV62452728; called by muse, mutect2, varscan2
- DSG4 | c.390G>A p.L130= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV57388106; called by muse, mutect2, varscan2
- DSG4 | c.798C>T p.F266= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV57388130; called by muse, mutect2, varscan2
- DYNC1I1 | c.279A>T p.P93= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV61455344; called by muse, mutect2, varscan2
- EPHA7 | c.2196C>T p.V732= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV65176996; called by muse, mutect2, varscan2
- ERC2 | c.411C>T p.S137= | Silent (SNP) | VAF 43/190 reads (23%) | catalogued as COSV55599007; called by muse, mutect2, varscan2
- F13B | c.1071G>A p.G357= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs775799552, COSV66372121; called by muse, mutect2, varscan2
- FAM83H | c.3501C>T p.F1167= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs781824187, COSV62027237; called by muse, mutect2, varscan2
- FBXO39 | c.921G>A p.P307= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs764013991, COSV58620917; called by muse, mutect2, varscan2
- FCER1A | c.643C>T p.L215= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1194761458, COSV100929244, COSV63668662; called by mutect2, varscan2
- FLNB | c.6006C>T p.A2002= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV55869618; called by muse, mutect2, varscan2
- FMN2 | c.3073C>T p.L1025= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, varscan2
- FOSL2 | c.252C>T p.P84= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV99268254; called by muse, mutect2, varscan2
- GABRB3 | c.675C>T p.F225= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs201004195; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRR1 | c.726G>A p.R242= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV65618726, COSV65620687; called by muse, mutect2, varscan2
- GALNT14 | c.438C>T p.I146= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV61102263; called by muse, mutect2, varscan2
- GALNT17 | c.1002G>A p.R334= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV61146812; called by muse, mutect2, varscan2
- GLYATL2 | c.549G>A p.G183= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54848903; called by muse, mutect2, varscan2
- GNA13 | c.387C>T p.A129= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV71474352; called by muse, mutect2, varscan2
- GPR156 | c.1398C>T p.S466= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs1343744971, COSV59937874; called by muse, mutect2, varscan2
- GRIN2B | c.288G>A p.G96= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as rs200172066, COSV101662959; called by muse, mutect2, varscan2
- GUCY2D | c.2010G>A p.R670= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs775825051, COSV54694337; called by muse, mutect2, varscan2
- H1-5 | c.408G>A p.G136= | Silent (SNP) | VAF 66/237 reads (28%) | catalogued as COSV100137763; called by muse, mutect2, varscan2
- HDAC9 | c.1032G>A p.S344= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs765691093, COSV67766266; called by muse, mutect2, varscan2
- HDHD5 | c.583C>T p.L195= (on ENST00000336737 / NM_033070.3; = p.L165= on NM_017829.5) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs770394047, COSV50084387; called by muse, mutect2
- HEATR6 | c.3312C>T p.S1104= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV51743546; called by muse, mutect2, varscan2
- HHIPL2 | c.489G>A p.R163= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV58563104, COSV58563524; called by muse, mutect2, varscan2
- HIPK1 | c.1917C>T p.T639= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV61245695; called by muse, mutect2, varscan2
- HMGXB4 | c.1239C>T p.A413= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV53332719; called by muse, mutect2, varscan2
- HNRNPCL1 | c.603G>A p.L201= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs766780820, COSV100508859; called by muse, mutect2, varscan2
- HOXB8 | c.15C>T p.F5= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV53309831; called by muse, mutect2
- HUWE1 | c.9684C>T p.S3228= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV53333891; called by muse, mutect2, varscan2
- HYDIN | c.6564C>T p.I2188= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1490984292, COSV59248766; called by muse, mutect2, varscan2
- IGHA2 | c.360C>T p.A120= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- IGHV4-61 | c.81C>T p.G27= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs1555560728; called by muse, mutect2, varscan2
- IGSF1 | c.2304G>A p.L768= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV63835934; called by muse, mutect2, varscan2
- IMPDH1 | c.660C>T p.I220= (on ENST00000470772 / NM_001142573.2; = p.I306= on NM_000883.4) | Silent (SNP) | VAF 59/168 reads (35%) | catalogued as COSV58314900; called by muse, mutect2, varscan2
- INHA | c.921C>T p.V307= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as COSV54712417; called by muse, mutect2, varscan2
- INSM1 | c.1212C>T p.A404= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV59604434; called by muse, mutect2
- IVL | c.282G>A p.Q94= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs536297759, COSV64215428; called by muse, mutect2, varscan2
- KAT6B | c.1569C>T p.S523= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV99767572; called by muse, mutect2, varscan2
- KDM2B | c.1018C>A p.R340= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs368219190, COSV100997292; called by muse, mutect2, varscan2
- KDM2B | c.1017G>A p.L339= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100997293; called by muse, mutect2, varscan2
- KIF4B | c.3063C>T p.I1021= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as rs1370295040, COSV70527125; called by muse, mutect2, varscan2
- KRTAP1-1 | c.369C>T p.C123= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- LRP2 | c.12321G>A p.G4107= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV55539959; called by muse, mutect2, varscan2
- LRRC37A3 | c.2137C>T p.L713= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100140930; called by mutect2, varscan2
- LRRC6 | c.951C>T p.I317= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV51537569; called by muse, mutect2, varscan2
- MAEL | c.639C>T p.I213= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV63112271, COSV63112317; called by muse, mutect2, varscan2
- MARCO | c.609G>A p.E203= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV59051496; called by muse, mutect2, varscan2
- MGLL | c.657G>A p.R219= (on ENST00000398104 / NM_001003794.2; = p.R229= on NM_007283.6) | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV54022294; called by muse, mutect2, varscan2
- MROH7 | c.3111C>T p.A1037= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV59867705; called by muse, mutect2, varscan2
- MUC3A | c.8166G>A p.V2722= | Silent (SNP) | VAF 82/386 reads (21%) | catalogued as rs1004119959; called by muse, mutect2
- MYG1 | c.819G>A p.K273= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs765755479, COSV52932108; called by muse, mutect2, varscan2
- MYH13 | c.975C>T p.I325= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV52820333; called by muse, mutect2, varscan2
- MYLK | c.1614G>A p.R538= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV60604315, COSV60608367; called by muse, mutect2, varscan2
- MYO5A | c.2022G>A p.E674= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV62556427; called by muse, mutect2, varscan2
- MYOM3 | c.2985G>A p.K995= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV58389362; called by muse, mutect2, varscan2
- NAV3 | c.1668T>C p.T556= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV57060554; called by muse, mutect2, varscan2
- NDUFV2 | c.564A>T p.I188= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV59186762; called by muse, mutect2, varscan2
- NEB | c.7231C>T p.L2411= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV50807279; called by muse, mutect2, varscan2
- NEB | c.4461C>T p.S1487= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs753328294, COSV50807307; called by mutect2, varscan2
- NEXMIF | c.2700C>T p.F900= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV50021650, COSV99280372; called by muse, mutect2, varscan2
- NFIA | c.1023C>T p.S341= | Silent (SNP) | VAF 37/185 reads (20%) | catalogued as rs1490836971, COSV64533505; called by muse, mutect2, varscan2
- NOLC1 | c.147C>T p.S49= | Silent (SNP) | VAF 91/171 reads (53%) | catalogued as rs1388019435, COSV64179861; called by muse, mutect2, varscan2
- NOS1 | c.3474C>T p.F1158= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as COSV57606346; called by muse, mutect2, varscan2
- NOTUM | c.846G>A p.T282= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV68825717; called by muse, mutect2, varscan2
- NRIP3 | c.240C>T p.P80= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV58468799; called by muse, mutect2, varscan2
- NUP210L | c.3270G>A p.E1090= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV55141080; called by muse, mutect2, varscan2
- NYAP2 | c.1314C>T p.S438= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs562881458, COSV55997743; called by muse, mutect2, varscan2
- NYNRIN | c.210G>A p.K70= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV66841035; called by muse, mutect2, varscan2
- OBSCN | c.11313C>T p.I3771= | Silent (SNP) | VAF 46/163 reads (28%) | catalogued as rs1474401852, COSV52737940; called by muse, mutect2, varscan2
- OR10H2 | c.231C>T p.I77= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV59945324; called by muse, mutect2, varscan2
- OR2A14 | c.915G>A p.R305= | Silent (SNP) | VAF 66/207 reads (32%) | catalogued as rs534861677, COSV68717873; called by muse, mutect2, varscan2
- OR4C6 | c.876G>A p.V292= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs772862034, COSV58602377; called by muse, mutect2, varscan2
- OR4D2 | c.12G>A p.G4= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV73459690; called by muse, mutect2, varscan2
- OR4K14 | c.186C>T p.F62= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59292045; called by muse, mutect2, varscan2
- OR51E1 | c.75G>A p.E25= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV101211547, COSV67809313; called by muse, mutect2, varscan2
- OR52E8 | c.540C>T p.I180= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV66204524; called by muse, mutect2, varscan2
- OR56A3 | c.291C>T p.S97= | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as rs554775961, COSV61568499; called by muse, varscan2
- OR5J2 | c.312C>T p.F104= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs373119214; called by muse, mutect2, varscan2
- OR5P2 | c.837C>T p.P279= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs1253121245, COSV61489868; called by muse, mutect2
- P3H2 | c.1860C>T p.F620= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs370201984; called by muse, mutect2, varscan2
- PAPPA2 | c.4143G>A p.Q1381= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100868055, COSV62790335; called by muse, mutect2, varscan2
- PCDHAC2 | c.171C>T p.L57= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53836253; called by muse, mutect2, varscan2
- PCDHB10 | c.909C>A p.L303= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV53375016; called by muse, mutect2, varscan2
- PCDHB7 | c.1479C>T p.S493= | Silent (SNP) | VAF 113/222 reads (51%) | catalogued as rs1271150949, COSV50753730; called by muse, mutect2, varscan2
- PCDHGA5 | c.825G>A p.G275= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV53895210; called by muse, mutect2, varscan2
- PDCD11 | c.2790G>A p.A930= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs745376870, COSV63932952; called by muse, mutect2, varscan2
- PDE4A | c.2613C>T p.S871= (on ENST00000380702 / NM_001111307.2; = p.S632= on NM_006202.3) | Silent (SNP) | VAF 68/130 reads (52%) | catalogued as rs764158449, COSV53350488; called by muse, mutect2, varscan2
- PLCB2 | c.1071G>A p.E357= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV53030679; called by muse, mutect2, varscan2
- PLCE1 | c.297G>A p.A99= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs768443933, COSV53335915; called by muse, mutect2, varscan2
- POLR2A | c.1014C>A p.S338= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1159743328, COSV59489016; called by muse, mutect2, varscan2
- PRUNE2 | c.399G>A p.Q133= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV65026380; called by muse, mutect2, varscan2
- PRXL2A | c.372C>T p.F124= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as COSV64690514; called by muse, mutect2, varscan2
- PSG9 | c.33G>A p.Q11= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV52483250; called by muse, mutect2, varscan2
- PSMC3IP | c.132G>A p.K44= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1424977361, COSV53815993; called by muse, mutect2, varscan2
- PTCRA | c.85C>T p.L29= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs753748329, COSV58975180; called by muse, mutect2, varscan2
- PTPRD | c.4161G>A p.A1387= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs201122675, COSV61926784; called by muse, mutect2, varscan2
- RASD2 | c.286C>T p.L96= | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as COSV53351894; called by muse, mutect2, varscan2
- RBL2 | c.513G>A p.Q171= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV50872822; called by muse, mutect2, varscan2
- REEP2 | c.210C>T p.I70= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as rs775288391, COSV54734394; called by muse, mutect2, varscan2
- RHOT1 | c.1092C>T p.S364= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV61713578; called by muse, mutect2, varscan2
- RNF135 | c.1164C>T p.A388= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV60432899; called by muse, mutect2, varscan2
- RNPS1 | c.723C>T p.P241= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57042704; called by muse, mutect2
- RSPH6A | c.1167G>A p.E389= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV55569861; called by muse, mutect2, varscan2
- RTL3 | c.924C>T p.F308= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV58183099; called by muse, mutect2, varscan2
- RUNDC1 | c.801T>G p.V267= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV64511436; called by muse, mutect2
- RUNDC3B | c.885C>T p.N295= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1218970072, COSV100406872; called by muse, mutect2, varscan2
- RYR1 | c.2331C>T p.F777= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1210759640, COSV62088175; called by muse, mutect2, varscan2
- RYR2 | c.14142C>T p.F4714= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV63659499; called by muse, mutect2, varscan2
- SCAPER | c.1116T>A p.A372= | Silent (SNP) | VAF 61/104 reads (59%) | catalogued as COSV57733362; called by muse, mutect2, varscan2
- SCN8A | c.5199G>A p.K1733= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV61976090; called by muse, mutect2, varscan2
- SDC3 | c.846C>T p.A282= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100232169; called by muse, mutect2, varscan2
- SHBG | c.243G>A p.E81= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52646109; called by muse, mutect2, varscan2
- SLC14A2 | c.1041C>T p.S347= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs752684310, COSV54905936, COSV54912466; called by muse, mutect2, varscan2
- SLC22A16 | c.1581C>T p.T527= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV57926995; called by muse, mutect2, varscan2
- SLC27A6 | c.264G>A p.R88= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as rs1439156179, COSV52479138; called by muse, mutect2, varscan2
- SLC4A2 | c.2493C>T p.I831= | Silent (SNP) | VAF 69/245 reads (28%) | catalogued as COSV52538978; called by muse, mutect2, varscan2
- SLC6A18 | c.915C>T p.I305= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs781108917, COSV57249449; called by muse, mutect2, varscan2
- SLC8A3 | c.213G>A p.G71= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs868211211, COSV63518820, COSV63524890; called by muse, mutect2, varscan2
- SLFN11 | c.2019C>T p.F673= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as COSV57697321; called by muse, mutect2, varscan2
- SMARCA4 | c.1404C>T p.R468= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs995631496, COSV100758259; ClinVar: likely benign; called by muse, mutect2
- SMC4 | c.3612A>G p.V1204= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs1240333486, COSV59086329; called by muse, mutect2, varscan2
- SPDEF | c.372C>T p.S124= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV65000536; called by muse, mutect2, varscan2
- SRMS | c.801C>T p.L267= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV53915806, COSV53916646; called by muse, mutect2, varscan2
- TAF1 | c.303C>T p.S101= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV52107959; called by muse, mutect2, varscan2
- TANGO6 | c.600G>A p.K200= | Silent (SNP) | VAF 83/219 reads (38%) | catalogued as COSV55759984; called by muse, mutect2, varscan2
- TAS1R3 | c.1305C>T p.F435= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs780086420, COSV59562105; called by muse, mutect2, varscan2
- TCAF1 | c.2310C>T p.F770= | Silent (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- TELO2 | c.180G>T p.S60= | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as COSV51975907, COSV51976688; called by muse, mutect2, varscan2
- TEX15 | c.5949C>T p.H1983= (on ENST00000256246; = p.H2366= on NM_001350162.2) | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV56341243; called by muse, mutect2, varscan2
- TF | c.1200C>T p.I400= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs765167285, COSV53917412, COSV53920039; called by muse, mutect2, varscan2
- THBS1 | c.201C>T p.I67= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs747664282, COSV52949806; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3943C>T p.L1315= | Silent (SNP) | VAF 58/225 reads (26%) | catalogued as rs780561452, COSV64099859; called by muse, mutect2, varscan2
- TOP3B | c.1317C>T p.L439= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV64116286; called by muse, varscan2
- TOX2 | c.423G>A p.S141= (on ENST00000358131 / NM_001098798.2; = p.S90= on NM_032883.3) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1291241720, COSV57882033; called by muse, mutect2, varscan2
- TRANK1 | c.2622C>T p.I874= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs866510996, COSV57139793; called by muse, mutect2, varscan2
- TRIM55 | c.303G>A p.V101= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV52543223; called by muse, mutect2, varscan2
- TRIM58 | c.1347C>T p.F449= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV63569018; called by muse, mutect2, varscan2
- TRPV6 | c.384C>T p.L128= | Silent (SNP) | VAF 67/179 reads (37%) | catalogued as COSV63890330; called by muse, mutect2, varscan2
- TTN | c.69921G>A p.K23307= (on ENST00000591111; = p.K15883= on NM_003319.4) | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs371884545; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UBOX5 | c.555C>T p.I185= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV53904087; called by muse, mutect2, varscan2
- UGGT2 | c.3999T>C p.D1333= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs1335847824, COSV65072100; called by muse, mutect2, varscan2
- UGT2A2 | c.546C>T p.F182= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV54137895; called by muse, mutect2, varscan2
- UGT3A2 | c.1038G>A p.V346= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV56928068; called by muse, mutect2, varscan2
- UNC5B | c.1563C>T p.F521= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV58974131; called by muse, mutect2, varscan2
- VCAN | c.1002C>T p.F334= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as rs754539391; called by muse, mutect2, varscan2
- VIPR1 | c.825C>T p.I275= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs748932120, COSV57296398; called by muse, mutect2, varscan2
- WNT9B | c.972C>T p.S324= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV51517255, COSV51519189; called by muse, mutect2, varscan2
- ZFP82 | c.1476C>T p.S492= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV67564526; called by muse, mutect2, varscan2
- ZNF292 | c.3825C>T p.F1275= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV60535300; called by mutect2, varscan2
- ZNF442 | c.114C>T p.F38= | Silent (SNP) | VAF 49/95 reads (52%) | catalogued as rs557660391, COSV54420197; called by muse, mutect2, varscan2
- ZNF485 | c.867G>A p.Q289= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV62423553; called by muse, mutect2
- ZSCAN2 | c.1263C>T p.S421= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs1311814566, COSV57571811; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95665031 C>T | 3'Flank (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- AL136982.4 | n.671C>T | RNA (SNP) | VAF 69/159 reads (43%) | catalogued as rs1185938793; called by muse, mutect2, varscan2
- FAM184A | c.1815+315C>T | Intron (SNP) | VAF 13/54 reads (24%) | catalogued as rs1368934830, COSV100137525; called by muse, mutect2, varscan2
- HEPACAM2 | c.80-12C>T | Intron (SNP) | VAF 39/72 reads (54%) | catalogued as COSV59059027; called by muse, mutect2, varscan2
- HIF3A | c.877+105C>T | Intron (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671130 G>A | 3'Flank (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- NACA | c.71-2796C>T | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100771164; called by muse, mutect2, varscan2
- NTRK3 | c.1586-38643C>T | Intron (SNP) | VAF 64/122 reads (52%) | catalogued as COSV100446045; called by muse, mutect2, varscan2
- NXF5 | n.829A>T | RNA (SNP) | VAF 42/88 reads (48%) | catalogued as COSV53789571; called by muse, mutect2, varscan2
- OBSCN | c.18662-1923C>T | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99475004; called by muse, mutect2, varscan2
- OR52A4P | n.915C>T | RNA (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1637-187C>T | Intron (SNP) | VAF 9/36 reads (25%) | catalogued as rs761819159; called by muse, mutect2, varscan2
- SNORD116-14 | n.5C>T | RNA (SNP) | VAF 35/173 reads (20%) | catalogued as rs754520678; called by muse, mutect2, varscan2
- TCF20 | c.*55G>A | 3'UTR (SNP) | VAF 28/76 reads (37%) | catalogued as COSV100166371; called by muse, mutect2, varscan2
